Somatic mutation profile of tumor specimen TCGA-AJ-A3BG-01A (aliquot TCGA-AJ-A3BG-01A-11D-A19Y-09) from TCGA case TCGA-AJ-A3BG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 65.3 years (23,861 days).
Specimen TCGA-AJ-A3BG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ed2ab38-599a-45d4-a206-337d86c261c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3BG-10A (Blood Derived Normal), aliquot TCGA-AJ-A3BG-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca2e058f-2f51-4d30-ae2f-ec9f326f665f

The open-access MAF lists 1,577 somatic variants for this specimen: 1,178 protein-altering or splice-affecting, 361 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 868, Silent 361, Frame Shift Del 190, Nonsense Mutation 47, Frame Shift Ins 35, Intron 18, In Frame Del 14, Splice Site 12, Splice Region 10, 3'Flank 6, RNA 6, 3'UTR 5.

Variants (750 of 1,577; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 19/38 reads (50%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KANSL1 | c.779dup p.V261Cfs*6 | Frame Shift Ins (INS) | VAF 7/38 reads (18%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 12/37 reads (32%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.5483G>A p.R1828Q | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587783978, CM051566, COSV56942450; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NOTCH1 | c.1070_1072del p.F357del | In Frame Del (DEL) | VAF 25/54 reads (46%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PAFAH1B1 | c.910del p.S304Vfs*29 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs587784292; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1057519942, COSV55881590; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776934, CM126686, COSV55846573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RAG1 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs878853004, CM1514428, COSV55027461; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SALL4 | c.2713C>T p.R905* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs74315428, CM060468, COSV99409642; ClinVar: pathogenic; called by muse, varscan2
- TBC1D20 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as rs587777157, CM1312371, COSV62613291; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TBL1XR1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as rs1057517933, CM162314, COSV70501537; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 25/48 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AANAT | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745917967, COSV99166233; called by muse, mutect2, varscan2
- ABCA12 | c.7516C>A p.L2506M (on ENST00000272895 / NM_173076.3; = p.L2188M on NM_015657.3) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.719); catalogued as COSV99790416; called by muse, mutect2, varscan2
- ABCA3 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs201681616; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA7 | c.5653C>T p.R1885C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs149423196; called by muse, mutect2, varscan2
- ABCA8 | c.2674G>A p.V892M | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV99286114; called by muse, mutect2, varscan2
- ABCG4 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764693748, COSV56645862; called by muse, mutect2, varscan2
- ABHD1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as rs150925501, COSV99574883; called by muse, mutect2, varscan2
- ABL2 | c.503T>A p.L168Q (on ENST00000502732 / NM_007314.4; = p.L153Q on NM_005158.5) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100772823; called by muse, mutect2, varscan2
- ABRA | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745915544, COSV61732533; called by muse, mutect2, varscan2
- AC004593.2 | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs138853951; called by muse, mutect2, varscan2
- ACACB | c.5777T>C p.V1926A | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV100623023; called by muse, mutect2, varscan2
- ACOXL | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs191705193; called by muse, mutect2, varscan2
- ACP4 | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54518295; called by muse, mutect2
- ACP7 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs758182407, COSV100488530, COSV58698166; called by muse, mutect2, varscan2
- ACSM5 | c.323del p.G108Vfs*11 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs746947661, COSV59374153; called by mutect2, pindel, varscan2
- ACTL9 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs782351721, COSV61005000, COSV61005136; called by muse, mutect2, varscan2
- ACTR8 | c.124-2A>C p.X42_splice | Splice Site (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99213745; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 20/38 reads (53%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM19 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as COSV99977549; called by muse, mutect2, varscan2
- ADAM7 | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.047); catalogued as rs112329833, COSV51542068; called by muse, mutect2, varscan2
- ADAM8 | c.2345dup p.V783Sfs*17 | Frame Shift Ins (INS) | VAF 22/60 reads (37%) | catalogued as rs774290950; called by mutect2, pindel, varscan2
- ADAM8 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs759368536, COSV101291604; called by muse, mutect2, varscan2
- ADAMTS13 | c.1705+2T>C p.X569_splice | Splice Site (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100747119; called by muse, mutect2, varscan2
- ADAMTS13 | c.4120C>T p.Q1374* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99390331; called by muse, mutect2, varscan2
- ADAMTS2 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs144554943, COSV52381631; called by muse, mutect2, varscan2
- ADAP1 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs369529776; called by muse, mutect2, varscan2
- ADCY3 | c.2486G>T p.G829V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99568461; called by muse, mutect2, varscan2
- ADGRA2 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100178094; called by muse, mutect2, varscan2
- ADGRE3 | c.762del p.F254Lfs*12 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs762974450; called by mutect2, pindel, varscan2
- ADIRF | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1419885700, COSV100920986; called by mutect2, varscan2
- ADRA1B | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs781709695, COSV100140276; called by muse, mutect2, varscan2
- ADRA2A | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375454021, COSV54529651; called by muse, mutect2, varscan2
- ADRB2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100019235; called by muse, mutect2, varscan2
- AF196969.1 | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.498); catalogued as COSV99339356; called by muse, mutect2, varscan2
- AGBL4 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376443097; called by muse, mutect2, varscan2
- AGPAT4 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs776508549, COSV100211597; called by muse, varscan2
- AHCY | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.245); catalogued as rs749200122, COSV99464282; called by muse, mutect2, varscan2
- AHNAK2 | c.13759G>A p.V4587M | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as rs779279676, COSV100317893; called by muse, mutect2, varscan2
- AHNAK2 | c.10004C>T p.A3335V | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.072); catalogued as rs371364837; called by muse, mutect2, varscan2
- AKAP6 | c.4048G>A p.A1350T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs138243272; called by muse, mutect2, varscan2
- AKNA | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs139873776; called by muse, mutect2, varscan2
- AL121899.2 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as COSV101198511; called by muse, mutect2, varscan2
- ALG10B | c.886del p.S296Hfs*23 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | catalogued as rs1397842268; called by mutect2, pindel, varscan2
- ALMS1 | c.5084C>T p.P1695L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.642); catalogued as rs756796770, COSV100042787; called by muse, mutect2, varscan2
- ALOX15 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs377228606; called by muse, mutect2, varscan2
- ALOX5 | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs866340744, COSV100980086; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 14/27 reads (52%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- ALX1 | c.682G>T p.G228* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as COSV100374481; called by muse, mutect2, varscan2
- ALX1 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100374482; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4594del p.R1532Gfs*5 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | catalogued as COSV51845823; called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.5858G>A p.R1953Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.207); catalogued as rs1436807955, COSV99783650; called by muse, mutect2, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKK1 | c.2023G>A p.V675I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV100392911; called by muse, varscan2
- ANKK1 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs768579058, COSV58274158; called by muse, varscan2
- ANKS1B | c.1090T>C p.S364P | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.622); catalogued as COSV100246254; called by muse, mutect2
- ANKS1B | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61357106; called by muse, mutect2, varscan2
- ANXA13 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as rs779057517, COSV51622959; called by muse, mutect2, varscan2
- ANXA4 | c.478-2A>G p.X160_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as COSV101268811; called by muse, mutect2, varscan2
- AR | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.102); catalogued as rs1213709903, COSV65954613; called by muse, mutect2, varscan2
- ARHGAP33 | c.2821C>T p.R941C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs750159033, COSV50119326; called by muse, mutect2, varscan2
- ARHGAP39 | c.2629C>T p.H877Y (on ENST00000276826 / NM_001308208.2; = p.H908Y on NM_025251.2) | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV99431574; called by muse, mutect2, varscan2
- ARHGAP4 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs782349092, COSV63131139; called by muse, mutect2, varscan2
- ARHGEF25 | c.1267C>A p.L423I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1167204700, COSV99678073; called by muse, mutect2, varscan2
- ARID1A | c.2129G>A p.R710H | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1171422700, COSV100252114; called by muse, mutect2, varscan2
- ARMC5 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs772950226, COSV99192588; called by muse, mutect2, varscan2
- ARSI | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.418); catalogued as rs777249696, COSV60817364; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 9/16 reads (56%) | catalogued as rs753865255; called by mutect2, varscan2
- ASH1L | c.6451C>T p.R2151* (on ENST00000368346 / NM_001366177.2; = p.R2146* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 25/40 reads (63%) | catalogued as COSV64207258; called by muse, mutect2, varscan2
- ASIC2 | c.705A>G p.T235= | Splice Region (SNP) | VAF 17/47 reads (36%) | catalogued as COSV56761350; called by muse, mutect2, varscan2
- ASPM | c.6494C>T p.T2165I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs907757922, COSV99660587; called by muse, mutect2, varscan2
- ASTN1 | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.463); catalogued as COSV56080719, COSV99922120; called by muse, mutect2, varscan2
- ATAD5 | c.1373del p.N458Mfs*14 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs1256945229; called by mutect2, varscan2
- ATP10B | c.3269G>A p.R1090H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs769788084, COSV100515193; called by muse, mutect2, varscan2
- ATP13A2 | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100454209; called by muse, mutect2, varscan2
- ATP2B2 | c.1309G>A p.V437M (on ENST00000352432; = p.V403M on NM_001683.5) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1276448598, COSV59493220; called by muse, mutect2, varscan2
- ATP7A | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100431047, COSV58441915; called by muse, mutect2, varscan2
- ATP8B2 | c.3118G>A p.V1040M (on ENST00000672630; = p.V1007M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.493); catalogued as rs376001580, COSV100528047; called by muse, mutect2, varscan2
- ATR | c.6976T>C p.C2326R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs766127973, COSV100638302; called by muse, mutect2, varscan2
- ATXN2L | c.2668G>C p.A890P | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100294566; called by muse, mutect2, varscan2
- AXIN2 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100196600; called by mutect2, varscan2
- BACE1 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.894); catalogued as rs762721077, COSV100475142; called by muse, mutect2, varscan2
- BAIAP2 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.841); catalogued as COSV100348319; called by muse, mutect2, varscan2
- BCL11B | c.779C>T p.T260M (on ENST00000357195 / NM_001282237.2; = p.T189M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756798054, COSV61738723; called by muse, mutect2, varscan2
- BCL6B | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs200507334, COSV53427105; called by muse, mutect2, varscan2
- BCOR | c.19del p.L7Cfs*9 | Frame Shift Del (DEL) | VAF 17/32 reads (53%) | catalogued as COSV60718182; called by mutect2, pindel, varscan2
- BCR | c.2599_2601del p.K867del | In Frame Del (DEL) | VAF 26/48 reads (54%) | catalogued as rs749914877; called by pindel, varscan2
- BPGM | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs746836937, COSV100790194; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs763134487; called by mutect2, varscan2
- BRPF1 | c.2380G>A p.D794N | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs764575036, COSV100121298; called by muse, mutect2, varscan2
- BSN | c.8464G>A p.V2822M | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754734296, COSV56521961; called by muse, mutect2, varscan2
- BTN2A1 | c.1325C>A p.P442H | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100438638; called by muse, mutect2, varscan2
- C11orf68 | c.134C>T p.T45M (on ENST00000530188; = p.T86M on NM_031450.4) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as rs763705751, COSV56988147; called by muse, mutect2, varscan2
- C8B | c.287A>G p.H96R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1042370531, COSV100980797; called by muse, mutect2, varscan2
- C9orf131 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs764639446, COSV56613578, COSV56615458; called by muse, mutect2, varscan2
- CABIN1 | c.5641G>A p.V1881M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV99573461; called by muse, mutect2, varscan2
- CACNA1B | c.6979C>T p.R2327W | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765789569, COSV53142151; called by muse, mutect2, varscan2
- CACNA1C | c.1435G>A p.V479M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs752677964, COSV100219566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1C | c.3080G>A p.R1027Q | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV59747910, COSV59785774; called by muse, mutect2, varscan2
- CACNA1D | c.1591G>A p.V531I (on ENST00000350061 / NM_001128840.3; = p.V551I on NM_000720.4) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs199772983, COSV99858612; called by muse, mutect2, varscan2
- CACNA1E | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); catalogued as rs1305652887, COSV62386898; called by muse, mutect2, varscan2
- CACNA1E | c.5272C>T p.R1758C | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs963141863, COSV100703285; called by muse, mutect2, varscan2
- CACNA1H | c.4738C>T p.R1580C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs777159526, COSV61986127; called by muse, mutect2, varscan2
- CACNA2D3 | c.663T>A p.F221L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV55512063, COSV55526249; called by muse, mutect2, varscan2
- CALN1 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as rs1036919510, COSV67953968; called by muse, mutect2, varscan2
- CALU | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs569487134, COSV50823286, COSV99975725; called by muse, mutect2, varscan2
- CALU | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV99975726; called by muse, mutect2, varscan2
- CAPN1 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0.356); catalogued as rs772985471, COSV99658730; called by muse, mutect2, varscan2
- CAPN3 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946415346, COSV58825831; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARD9 | c.1264G>A p.V422I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs374295826; called by muse, varscan2
- CASR | c.2006C>T p.A669V (on ENST00000490131; = p.A746V on NM_000388.4) | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs139417576, CM165801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASS4 | c.1997C>A p.P666H | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100824753, COSV64387828; called by muse, mutect2, varscan2
- CBFA2T3 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs181515376, COSV99241972; called by muse, mutect2, varscan2
- CBLB | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as rs535219619, COSV51431849; called by muse, mutect2, varscan2
- CCDC103 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764426959, COSV99493375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC136 | c.2788C>T p.R930W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199769669, COSV52801572, COSV99922428; called by muse, mutect2, varscan2
- CCDC157 | c.1334_1335+1del | In Frame Del (DEL) | VAF 22/50 reads (44%) | catalogued as rs768211536; called by pindel, varscan2
- CCDC17 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV100601850; called by muse, mutect2, varscan2
- CCDC183 | c.1392C>T p.G464= | Splice Region (SNP) | VAF 20/34 reads (59%) | catalogued as rs181529490; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 16/28 reads (57%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC88C | c.202A>G p.N68D | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV101104771; called by muse, mutect2, varscan2
- CCHCR1 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100883891; called by muse, mutect2
- CCL2 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV99861546; called by muse, mutect2, varscan2
- CCNF | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as rs138913390; called by muse, mutect2, varscan2
- CCNF | c.1990G>T p.G664* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99563774; called by muse, mutect2, varscan2
- CCR6 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs376263394; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD93 | c.943dup p.A315Gfs*34 | Frame Shift Ins (INS) | VAF 20/58 reads (34%) | catalogued as rs747115137; called by mutect2, varscan2
- CDC40 | c.1061G>T p.R354M | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1431578879, COSV100309409, COSV100309416; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs762194001; called by mutect2, varscan2
- CDK16 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99331771; called by muse, mutect2, varscan2
- CEACAM1 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99362392; called by muse, mutect2, varscan2
- CEACAM21 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV99494591; called by mutect2, varscan2
- CEACAM5 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as rs782477374, COSV55755564; called by muse, mutect2, varscan2
- CELSR3 | c.9854C>T p.P3285L | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as COSV99373835; called by muse, mutect2
- CELSR3 | c.9409C>T p.R3137C | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.04); catalogued as rs910673857, COSV51140153; called by muse, mutect2, varscan2
- CELSR3 | c.1505A>G p.D502G | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99373840; called by muse, mutect2, varscan2
- CENPL | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV100616380; called by muse, mutect2, varscan2
- CEP131 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs796803247, COSV99488479; called by muse, mutect2, varscan2
- CEP170 | c.3799C>T p.R1267C | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs764258155, COSV100317279; called by muse, mutect2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP350 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100854865; called by muse, mutect2, varscan2
- CEP85 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs141238912, COSV99432444; called by muse, varscan2
- CETP | c.1171T>C p.S391P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99570081; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 17/35 reads (49%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP69 | c.2745del p.K915Nfs*12 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as COSV100290203; called by mutect2, pindel, varscan2
- CFP | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs373595560, COSV99901506; called by muse, mutect2, varscan2
- CGB8 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1368576109, COSV100032054; called by muse, mutect2, varscan2
- CHD4 | c.3163C>T p.R1055C (on ENST00000357008 / NM_001363606.2; = p.R1068C on NM_001273.5) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894255; called by muse, mutect2, varscan2
- CHD4 | c.1801C>T p.R601C (on ENST00000357008 / NM_001363606.2; = p.R614C on NM_001273.5) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs369228909, COSV58907163; called by muse, mutect2, varscan2
- CHD8 | c.7112dup p.N2371Kfs*2 (on ENST00000646647 / NM_001170629.2; = p.N2092Kfs*2 on NM_020920.4) | Frame Shift Ins (INS) | VAF 30/69 reads (43%) | catalogued as rs751094013; called by mutect2, varscan2
- CHID1 | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100059905; called by muse, mutect2, varscan2
- CHPF | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs767216542, COSV60536203; called by muse, mutect2, varscan2
- CHRD | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770711370, COSV99200357; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA6 | c.462dup p.K155* | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | catalogued as rs35592906; called by mutect2, pindel, varscan2
- CHRNG | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs144755776; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST15 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs748902428, COSV60564798; called by muse, mutect2, varscan2
- CHSY1 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1219433912, COSV99573993; called by muse, mutect2, varscan2
- CLASP1 | c.3692del p.G1231Vfs*4 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | catalogued as rs749719822, COSV99752279; called by mutect2, pindel, varscan2
- CLMN | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.324); catalogued as COSV100112507; called by muse, mutect2
- CLSTN3 | c.2002C>A p.P668T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV99867171; called by muse, mutect2, varscan2
- CLUL1 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1475425621, COSV100620996; called by muse, mutect2, varscan2
- CNGA3 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99736925; called by muse, mutect2, varscan2
- CNNM1 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs764454140, COSV63201062; called by mutect2, varscan2
- CNNM3 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1360606313, COSV59709492; called by muse, mutect2, varscan2
- CNOT4 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs200823409; called by muse, mutect2, varscan2
- CNTROB | c.2699del p.G900Efs*34 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs35508310, COSV66608279; called by mutect2, pindel, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs374805044; called by mutect2, varscan2
- COL11A2 | c.1297C>T p.R433* (on ENST00000341947 / NM_080680.3; = p.R326* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV59495092; called by muse, mutect2
- COL15A1 | c.1185G>T p.E395D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as COSV100897813; called by muse, mutect2, varscan2
- COL1A1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1435869455, COSV56804765; called by muse, mutect2, varscan2
- COL24A1 | c.3353del p.K1118Rfs*7 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | catalogued as rs1170230275; called by mutect2, pindel, varscan2
- COL3A1 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100483188; called by muse, mutect2, varscan2
- COL5A1 | c.4753C>T p.R1585W | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs546865410, COSV65675928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764497780, COSV55999809; called by muse, mutect2
- COL8A1 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99657959; called by muse, mutect2, varscan2
- COLGALT1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.461); catalogued as rs1337578933, COSV99395112; called by muse, mutect2
- COLGALT1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs536730145, COSV53107527; called by muse, mutect2, varscan2
- COLGALT1 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs775094058, COSV99395115; called by muse, mutect2, varscan2
- COLGALT2 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs531974563, COSV62298989; called by muse, mutect2, varscan2
- COPG1 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs776568797, COSV100135702; called by muse, mutect2, varscan2
- CPNE7 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs372988583; called by muse, mutect2, varscan2
- CR2 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs529311780, COSV65507449; called by muse, mutect2, varscan2
- CRY2 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs777311984, COSV101314598; called by muse, mutect2, varscan2
- CSMD1 | c.8281G>A p.V2761M (on ENST00000520002; = p.V2760M on NM_033225.6) | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs753927140, COSV59279948; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.4844A>G p.D1615G (on ENST00000297405 / NM_001363185.1; = p.D1511G on NM_052900.3) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99837295; called by muse, mutect2, varscan2
- CTDSPL | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs747525595, COSV56205064; called by muse, mutect2, varscan2
- CTIF | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as rs764607946, COSV56491237; called by muse, mutect2, varscan2
- CTNNAL1 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100336609; called by muse, mutect2, varscan2
- CTTNBP2 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs199629667; called by muse, varscan2
- CUBN | c.8908C>T p.R2970C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs562374248, COSV64714804; ClinVar: uncertain significance; called by muse, mutect2
- CUBN | c.1775G>A p.G592D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as rs762094683, COSV100912901; called by muse, mutect2, varscan2
- CUL2 | c.606T>C p.F202= | Splice Region (SNP) | VAF 17/32 reads (53%) | catalogued as COSV101039185; called by muse, mutect2, varscan2
- CUL4A | c.2112G>A p.M704I (on ENST00000375440 / NM_001008895.4; = p.M604I on NM_003589.3) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58372099; called by muse, mutect2, varscan2
- CUL7 | c.2725G>A p.G909R | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1451203303, CM053192, COSV54816737, COSV99538792; called by muse, mutect2, varscan2
- CUX2 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV99919948; called by muse, mutect2, varscan2
- CWC22 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs761676860, COSV55426364, COSV55433719; called by muse, mutect2, varscan2
- CYP26B1 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); catalogued as rs1265502262, COSV50011085; called by muse, mutect2
- CYP2W1 | c.635del p.P212Lfs*33 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as COSV58269920; called by mutect2, pindel, varscan2
- CYP3A5 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs1401028894, COSV99769875; called by muse, mutect2, varscan2
- CYP46A1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55897113, COSV99952681; called by muse, mutect2, varscan2
- DBN1 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52794797; called by muse, mutect2, varscan2
- DBNDD1 | c.47C>T p.A16V (on ENST00000002501 / NM_001042610.3; = p.A36V on NM_024043.3) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99136496; called by muse, mutect2, varscan2
- DCC | c.2407G>A p.G803R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797044550, CM145928, COSV59121170; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCP2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs935909470, COSV101203920, COSV101203923; called by muse, mutect2, varscan2
- DCX | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as CM131047, COSV100576530; called by muse, mutect2, varscan2
- DDB2 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1218896761, COSV99921682; called by muse, mutect2, varscan2
- DDX4 | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100737587, COSV61757441; called by muse, mutect2, varscan2
- DENND1C | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1388651482, COSV101200212; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs553532837; called by mutect2, varscan2
- DENND3 | c.3275C>T p.A1092V | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs143494640, COSV52802946; called by muse, mutect2, varscan2
- DENND5A | c.2623G>A p.G875R | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.467); catalogued as rs1243650698, COSV100064828; called by muse, mutect2
- DGAT2 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.318); catalogued as COSV99929838; called by muse, mutect2
- DHPS | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs770020319, COSV99269640; called by muse, mutect2, varscan2
- DHRS3 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs904973071, COSV100879633; called by muse, mutect2, varscan2
- DHX16 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as COSV100905212; called by muse, mutect2, varscan2
- DHX57 | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs140333800; called by muse, mutect2, varscan2
- DIDO1 | c.5377C>T p.R1793* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV99826194; called by muse, mutect2, varscan2
- DIPK2B | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs747175485, COSV67640888; called by muse, mutect2, varscan2
- DIS3 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369590515; called by muse, mutect2, varscan2
- DLG3 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99529724; called by muse, mutect2, varscan2
- DLG3 | c.1751C>T p.T584M (on ENST00000374360 / NM_021120.4; = p.T247M on NM_020730.3) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.381); catalogued as rs777755684, COSV99529728; called by muse, mutect2, varscan2
- DLG5 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.184); catalogued as COSV100967574; called by muse, mutect2, varscan2
- DLGAP2 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1479852389, COSV101422128; called by muse, mutect2, varscan2
- DLK1 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as COSV100375276; called by muse, mutect2, varscan2
- DLL1 | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs201177310; called by muse, mutect2, varscan2
- DMBT1 | c.907T>C p.C303R | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353260; called by muse, mutect2, varscan2
- DMBT1 | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs371217158, COSV57544926; called by muse, mutect2, varscan2
- DNAH7 | c.3673C>T p.R1225C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780901030, COSV56753467; called by muse, mutect2, varscan2
- DNAH8 | c.3053G>A p.R1018H | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as rs777609925, COSV59464146, COSV59471463; called by muse, mutect2, varscan2
- DNAI3 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs575950333, COSV99641995; called by muse, mutect2, varscan2
- DNAJA2 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100398878; called by muse, mutect2, varscan2
- DNAJB12 | c.1132C>T p.R378C (on ENST00000338820; = p.R344C on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs775784238, COSV100123830; called by muse, mutect2, varscan2
- DNER | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs774454579, COSV100518794; called by muse, mutect2, varscan2
- DNM2 | c.2014C>T p.R672C (on ENST00000355667 / NM_001005360.3; = p.R668C on NM_004945.3) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs780219649, COSV58959840; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 40/66 reads (61%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK3 | c.5861G>A p.R1954Q | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs782707574, COSV56528136; called by muse, mutect2, varscan2
- DOCK5 | c.5466del p.S1824Afs*80 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | catalogued as rs34013556; called by mutect2, pindel, varscan2
- DOP1B | c.102G>A p.W34* | Nonsense Mutation (SNP) | VAF 9/11 reads (82%) | catalogued as COSV99535917; called by muse, mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 20/38 reads (53%) | catalogued as rs35482889; called by mutect2, varscan2
- DPH1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775796897, COSV53984499; called by muse, mutect2, varscan2
- DPP7 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.383); catalogued as rs777004339, COSV100857374; called by muse, mutect2, varscan2
- DPP8 | c.214_216del p.H72del (on ENST00000341861 / NM_001320875.2; = p.H56del on NM_017743.6) | In Frame Del (DEL) | VAF 21/45 reads (47%) | catalogued as rs1283438239; called by mutect2, pindel, varscan2
- DRD3 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs766862523, COSV99879506; called by muse, mutect2, varscan2
- DSCAML1 | c.3701G>T p.G1234V (on ENST00000321322; = p.G1174V on NM_020693.4) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100356296; called by muse, mutect2, varscan2
- DSCAML1 | c.3139G>A p.D1047N (on ENST00000321322; = p.D987N on NM_020693.4) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs753992533, COSV100356298; called by muse, mutect2, varscan2
- DSCAML1 | c.1738C>T p.R580W (on ENST00000321322; = p.R520W on NM_020693.4) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1172397068, COSV100356299, COSV58389260; called by muse, mutect2, varscan2
- DSP | c.3004C>T p.R1002W | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs772551736, COSV101131380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTX4 | c.1321G>A p.G441S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.959); catalogued as rs546051013, COSV99915561; called by muse, mutect2, varscan2
- DUSP16 | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as COSV99963203; called by muse, mutect2, varscan2
- DUSP26 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV99823499; called by muse, mutect2, varscan2
- DYNAP | c.112G>A p.V38I (on ENST00000321600; = p.V12I on NM_173629.3) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0.028); catalogued as rs377066854; called by muse, mutect2, varscan2
- DYNC1H1 | c.7357C>T p.R2453C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100795043; called by muse, mutect2, varscan2
- EFTUD2 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53656001; called by muse, mutect2, varscan2
- EGR3 | c.1128dup p.V377Rfs*30 | Frame Shift Ins (INS) | VAF 5/12 reads (42%) | catalogued as rs749768945; called by mutect2, varscan2
- EGR4 | c.1558C>T p.R520C (on ENST00000545030; = p.R417C on NM_001965.4) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771686012, COSV71531902; called by muse, mutect2
- EHMT1 | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); catalogued as rs1443023108, COSV100603988; called by muse, mutect2, varscan2
- EHMT2 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs776943251, COSV64995378; called by muse, mutect2, varscan2
- EIF3J | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99968931; called by muse, mutect2, varscan2
- ELAVL3 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100820799; called by muse, mutect2, varscan2
- ELMO1 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV100164832; called by muse, mutect2, varscan2
- ELN | c.1948G>A p.G650S (on ENST00000320399 / NM_001278939.1; = p.G617S on NM_000501.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); catalogued as rs781904032, COSV99332759; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EMC10 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100618505; called by muse, mutect2, varscan2
- EME2 | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.441); catalogued as rs528910143, COSV99457141; called by muse, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 12/23 reads (52%) | catalogued as rs770453803; called by mutect2, varscan2
- ENO3 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as rs201859879; called by muse, mutect2, varscan2
- ENOX1 | c.692A>G p.K231R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99816277; called by muse, mutect2, varscan2
- ENPEP | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs771608560, COSV54448004, COSV99487702; called by muse, mutect2, varscan2
- ENTPD4 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); catalogued as rs374788498; called by muse, mutect2, varscan2
- EP400 | c.4046C>T p.A1349V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.127); catalogued as rs541165241, COSV100201417; called by muse, mutect2, varscan2
- EP400 | c.5030G>A p.R1677H | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs368800722; called by muse, mutect2, varscan2
- EP400 | c.7157G>A p.R2386Q | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs777080714, COSV57787316; called by muse, varscan2
- EPHA10 | c.370_372del p.E124del | In Frame Del (DEL) | VAF 24/51 reads (47%) | catalogued as rs575794155; called by mutect2, pindel, varscan2
- EPHA3 | c.1938del p.E647Rfs*9 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs1467832547; called by mutect2, pindel, varscan2
- EPRS1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100859409; called by muse, mutect2, varscan2
- ERI1 | c.236T>C p.M79T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99141359; called by muse, mutect2, varscan2
- ERMP1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); catalogued as rs755097681, COSV99284579; called by muse, varscan2
- ESPL1 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as COSV57760975, COSV99229435; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 32/46 reads (70%) | catalogued as rs775950025; called by mutect2, varscan2
- EVL | c.1247C>T p.T416M (on ENST00000402714 / NM_001330221.2; = p.T418M on NM_016337.3) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.402); catalogued as rs748938976, COSV99979238; called by muse, varscan2
- F5 | c.529A>C p.N177H | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100889147; called by muse, mutect2, varscan2
- FAM102A | c.772C>T p.R258C (on ENST00000373095 / NM_001035254.3; = p.R116C on NM_203305.2) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs147692753; called by muse, mutect2, varscan2
- FAM126B | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV99627902; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM160A2 | c.2662G>A p.G888R (on ENST00000449352 / NM_001098794.2; = p.G902R on NM_032127.4) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs757901184, COSV99792170; called by muse, mutect2, varscan2
- FAM160A2 | c.2372C>T p.P791L (on ENST00000449352 / NM_001098794.2; = p.P805L on NM_032127.4) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99792172; called by muse, mutect2, varscan2
- FAM193A | c.1936G>A p.V646M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777617365, COSV100219313; called by muse, mutect2, varscan2
- FAM53C | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs760119242, COSV53512328; called by muse, mutect2, varscan2
- FAM90A1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1413442324, COSV56710140, COSV56711768; called by muse, mutect2, varscan2
- FAM98C | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs371060977; called by muse, mutect2, varscan2
- FARP1 | c.3097C>T p.R1033* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as rs549979587, COSV60330327; called by muse, mutect2, varscan2
- FARSA | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466031326, COSV100108877, COSV58905581; called by muse, mutect2, varscan2
- FARSB | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV99918445; called by muse, mutect2, varscan2
- FASN | c.4694C>T p.T1565M | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.443); catalogued as rs1294023345, COSV100147941; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN2 | c.3202C>T p.R1068W | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761958762, COSV52494404; called by muse, mutect2, varscan2
- FBN3 | c.7816G>A p.G2606R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs371456112; called by muse, mutect2
- FBXL4 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100014190; called by muse, mutect2, varscan2
- FBXO10 | c.2804C>T p.T935M | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs780753449, COSV52836912; called by muse, mutect2, varscan2
- FBXO31 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 107/261 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1373218571, COSV100291453; called by muse, mutect2, varscan2
- FBXW8 | c.540G>T p.W180C (on ENST00000309909; = p.W218C on NM_012174.1) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59301254; called by muse, mutect2, varscan2
- FCHSD1 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as rs761267623, COSV71300798; called by muse, mutect2, varscan2
- FCRL1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.732); catalogued as rs756516538, COSV100839699, COSV63823726; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FEM1B | c.1106A>G p.H369R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV100183687; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs748969702; called by mutect2, varscan2
- FGD3 | c.1831del p.L611Cfs*47 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as COSV61595555; called by mutect2, pindel, varscan2
- FGF16 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs782317053, COSV71546254; called by muse, mutect2, varscan2
- FGFR4 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52800741, COSV52801508; called by muse, mutect2, varscan2
- FILIP1L | c.3272G>A p.R1091Q (on ENST00000354552 / NM_182909.3; = p.R851Q on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs377075355, COSV58765934, COSV58772257; called by muse, mutect2, varscan2
- FLG | c.7159G>A p.G2387R | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs775764952, COSV100911672; called by muse, mutect2, varscan2
- FLNA | c.4438G>A p.V1480M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV61046068; called by muse, mutect2, varscan2
- FN1 | c.566A>G p.H189R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV60548349; called by muse, mutect2, varscan2
- FOXE1 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.57); catalogued as COSV100909942; called by muse, mutect2, varscan2
- FOXM1 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs375821639, COSV61206725; called by muse, mutect2, varscan2
- FOXP2 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs562313396, COSV63482535; called by muse, mutect2, varscan2
- FRMD3 | c.1780C>A p.L594M | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV100170931; called by muse, mutect2, varscan2
- FSCN3 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV99133815; called by muse, mutect2, varscan2
- FSTL1 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99820748; called by muse, mutect2, varscan2
- FTCD | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV99385170; called by muse, mutect2, varscan2
- FUT5 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.888); catalogued as COSV53137922, COSV99398829; called by muse, mutect2, varscan2
- G6PD | c.1043G>T p.R348M | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100855054; called by muse, mutect2, varscan2
- GAB3 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs138557356, COSV100850634; called by muse, mutect2, varscan2
- GALNS | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.243); catalogued as CM054749, COSV99243240; called by muse, mutect2, varscan2
- GAS2L2 | c.1226del p.P409Lfs*92 | Frame Shift Del (DEL) | VAF 19/44 reads (43%) | catalogued as rs782212939; called by mutect2, pindel, varscan2
- GATB | c.1640T>C p.I547T | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV99859087; called by muse, mutect2, varscan2
- GATC | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs896029723, COSV57571061; called by muse, mutect2, varscan2
- GDF2 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as rs782274691; called by muse, mutect2, varscan2
- GGCX | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV52089424; called by muse, mutect2, varscan2
- GHRH | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 45/96 reads (47%) | catalogued as rs377413593; called by muse, mutect2, varscan2
- GIGYF2 | c.322G>C p.G108R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779831949, COSV65247572, COSV65248489, COSV65249954; called by muse, mutect2, varscan2
- GIPC3 | c.685del p.A229Lfs*89 (on ENST00000644946; = p.A229Lfs*55 on NM_133261.3) | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | catalogued as rs748150647, COSV99056389; called by mutect2, pindel, varscan2
- GLI3 | c.2866C>T p.R956C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV67888299; called by muse, mutect2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs749150409; called by mutect2, varscan2
- GMPR | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs138267551; called by muse, mutect2, varscan2
- GNE | c.698G>A p.R233H (on ENST00000396594 / NM_001128227.3; = p.R202H on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs752650334, CM043291, COSV64951686; called by muse, mutect2, varscan2
- GNE | c.149G>A p.R50H (on ENST00000396594 / NM_001128227.3; = p.R19H on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64951454; called by muse, mutect2, varscan2
- GOT1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs772704095, COSV65147316; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs370114090; called by mutect2, varscan2
- GPC5 | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100994415; called by muse, mutect2, varscan2
- GPR146 | c.55T>C p.C19R | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99866411; called by muse, mutect2, varscan2
- GPR45 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1005354962, COSV51525398; called by muse, varscan2
- GPR45 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs1352198171, COSV51523131; called by muse, varscan2
- GPR78 | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.072); catalogued as rs572850332, COSV101223994; called by muse, mutect2, varscan2
- GPT2 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1318112700, COSV60837620; called by muse, mutect2, varscan2
- GSDME | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs375948210; called by muse, mutect2, varscan2
- GSE1 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV99496751; called by muse, mutect2, varscan2
- GSS | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.881); catalogued as COSV99404468; called by muse, mutect2, varscan2
- GUCA1B | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs564752140, COSV100027731; called by muse, mutect2, varscan2
- GUCY2D | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV99644057; called by muse, varscan2
- GZMH | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.73); catalogued as COSV99361974; called by muse, mutect2, varscan2
- H1-7 | c.674C>A p.T225N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100622227; called by muse, mutect2, varscan2
- H2AZ2 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs867152303, COSV99760519; called by muse, mutect2, varscan2
- H2BC3 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV63551659; called by muse, mutect2, varscan2
- HAS1 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748560541, COSV55786420; called by muse, mutect2, varscan2
- HCFC1 | c.4216G>A p.A1406T | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs782385254, COSV60078324; called by muse, mutect2, varscan2
- HCFC1 | c.2690C>T p.A897V | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs781971515, CM162097, COSV100129310; called by muse, mutect2, varscan2
- HCN4 | c.2465C>T p.T822M | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as rs201143364, COSV99983876; ClinVar: likely benign; called by muse, varscan2
- HECTD1 | c.6544G>A p.A2182T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101237416; called by muse, mutect2, varscan2
- HECTD4 | c.12718G>A p.A4240T | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs758133588, COSV101107798; called by muse, varscan2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 24/51 reads (47%) | catalogued as rs754540615; called by mutect2, pindel, varscan2
- HECW2 | c.2763del p.V922* | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as COSV99646682; called by mutect2, pindel, varscan2
- HELQ | c.2295G>T p.K765N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as rs757556391, COSV99787573, COSV99787837; called by muse, mutect2
- HELZ2 | c.6616dup p.R2206Pfs*42 (on ENST00000467148 / NM_001037335.2; = p.R1637Pfs*42 on NM_033405.3) | Frame Shift Ins (INS) | VAF 7/13 reads (54%) | catalogued as rs745497383; called by mutect2, varscan2
- HERC2 | c.13570G>A p.A4524T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); catalogued as rs144844826; called by muse, mutect2, varscan2
- HERC2 | c.9902C>T p.T3301I | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs534751272, COSV99874623; called by muse, mutect2, varscan2
- HHATL | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs865821800, COSV60041295, COSV60042840; called by muse, mutect2, varscan2
- HIVEP2 | c.4808G>A p.R1603Q | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs748022954, COSV50016791; called by muse, mutect2, varscan2
- HJURP | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs777949889, COSV64978762; called by muse, mutect2, varscan2
- HNF1B | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.513); catalogued as rs925595786, CM122521; called by muse, mutect2, varscan2
- HOXA11 | c.895del p.I299Lfs*30 | Frame Shift Del (DEL) | VAF 26/46 reads (57%) | catalogued as rs777829525; called by mutect2, varscan2
- HPCAL1 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV57145734; called by muse, varscan2
- HPS3 | c.2076G>A p.M692I | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV99937449; called by muse, mutect2, varscan2
- HSP90B1 | c.2386T>G p.S796A | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as COSV100236587; called by muse, mutect2, varscan2
- HSPA2 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs770917203, COSV99904834; called by muse, mutect2, varscan2
- HSPG2 | c.12058C>T p.R4020C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757191314, COSV100760825; called by muse, mutect2, varscan2
- HTR3B | c.133A>G p.K45E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV99492047; called by muse, mutect2, varscan2
- HTR4 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140360260; called by muse, mutect2, varscan2
- HYDIN | c.382A>T p.I128F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV99863612; called by muse, mutect2, varscan2
- IDH2 | c.435del p.T146Lfs*15 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IFNA14 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV101207318; called by muse, mutect2, varscan2
- IFT140 | c.3131G>A p.R1044H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs577498082, COSV99560028; called by muse, mutect2, varscan2
- IGDCC4 | c.996G>A p.L332= | Splice Region (SNP) | VAF 38/72 reads (53%) | catalogued as COSV100732956; called by muse, mutect2, varscan2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs765398170; called by mutect2, pindel, varscan2
- IGHE | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs782245796; called by muse, mutect2, varscan2
- IGLON5 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1171901550, COSV54536450; called by muse, varscan2
- IL12RB1 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100443073; called by muse, mutect2, varscan2
- IMPDH1 | c.1171G>A p.A391T (on ENST00000470772 / NM_001142573.2; = p.A477T on NM_000883.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs769089255, COSV100118714; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs760925109; called by mutect2, pindel
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs1561359523; called by mutect2, varscan2
- IRAK2 | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99844075; called by muse, mutect2, varscan2
- IRF2BP1 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100138918; called by muse, mutect2, varscan2
- ISCU | c.145G>A p.V49M (on ENST00000311893 / NM_213595.4; = p.V24M on NM_014301.4) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as rs371513074; called by muse, mutect2, varscan2
- ISLR2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV100679605, COSV100679631; called by muse, mutect2, varscan2
- ISM2 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs566061192, COSV53636666; called by muse, mutect2, varscan2
- ITFG1 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs1002924175, COSV57744548, COSV99076799; called by muse, mutect2, varscan2
- ITGA2B | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as rs571550200, CM093511, COSV52232475; called by muse, mutect2, varscan2
- ITPR1 | c.7515C>G p.C2505W (on ENST00000354582; = p.C2450W on NM_002222.7) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100231771; called by muse, mutect2, varscan2
- ITPR3 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as rs749099428, COSV65405535; called by muse, mutect2, varscan2
- ITPR3 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs752466498, COSV65405804; called by muse, mutect2, varscan2
- ITSN1 | c.3892G>T p.A1298S | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101182075; called by muse, mutect2, varscan2
- ITSN2 | c.4525G>T p.D1509Y | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100743707; called by muse, mutect2
- JARID2 | c.2661-1G>T p.X887_splice | Splice Site (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100521916; called by muse, mutect2, varscan2
- JPH1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs777573780, COSV60608760; called by muse, mutect2, varscan2
- JRK | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); catalogued as rs782347045, COSV70630469; called by muse, mutect2
- JUP | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs149623442; called by muse, mutect2, varscan2
- KANK3 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745651938, COSV100035556; called by muse, mutect2, varscan2
- KANSL1L | c.1978A>G p.N660D | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99910656; called by muse, mutect2, varscan2
- KCNG2 | c.644G>A p.C215Y | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV100301907; called by muse, mutect2, varscan2
- KCNH4 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99237381; called by muse, mutect2, varscan2
- KCNH4 | c.642dup p.S215Vfs*39 | Frame Shift Ins (INS) | VAF 13/33 reads (39%) | catalogued as rs753954093; called by mutect2, varscan2
- KCNS2 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99751238; called by muse, mutect2, varscan2
- KCNS3 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs144701569, COSV58407598; called by muse, mutect2, varscan2
- KDM3B | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs776949034, COSV58694965; called by muse, mutect2, varscan2
- KDSR | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768170793, COSV100430269; called by muse, mutect2, varscan2
- KEAP1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1412883238, COSV50283235, COSV50291239; called by muse, mutect2, varscan2
- KEAP1 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50480137, COSV99407912; called by muse, mutect2, varscan2
- KHDC4 | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100850821; called by muse, mutect2, varscan2
- KIAA0825 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100265854; called by muse, mutect2, varscan2
- KIAA1755 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs774534343, COSV99642200; called by mutect2, varscan2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 20/36 reads (56%) | catalogued as rs749990720; called by mutect2, varscan2
- KIF18B | c.2539G>A p.G847S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs201556743, COSV100192304; called by muse, mutect2, varscan2
- KIF21A | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1471900499, COSV62769499; called by muse, mutect2, varscan2
- KIF26A | c.1987G>A p.V663I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs751047912, COSV100181250; called by muse, mutect2, varscan2
- KIF3C | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs527663149, COSV99267500; called by muse, mutect2, varscan2
- KIFC2 | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as rs749425172, COSV100023846; called by muse, mutect2, varscan2
- KIFC3 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.6); PolyPhen benign (0.088); catalogued as rs781911915, COSV101109225; called by muse, mutect2, varscan2
- KIR3DL1 | c.879C>A p.C293* | Nonsense Mutation (SNP) | VAF 12/107 reads (11%) | catalogued as rs747304776; called by muse, mutect2
- KIRREL1 | c.2269G>A p.V757M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1452216377, COSV100779882; called by muse, mutect2, varscan2
- KLF17 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV64856510; called by muse, varscan2
- KLHL11 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.041); catalogued as COSV100044377; called by muse, mutect2, varscan2
- KLHL22 | c.1322G>A p.G441D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100186092; called by muse, mutect2, varscan2
- KLHL36 | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs770743658, COSV50722721; called by muse, mutect2, varscan2
- KMT2A | c.1333T>C p.S445P | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV100629073; called by muse, mutect2, varscan2
- KMT2A | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.644); catalogued as rs1264831726, COSV63283938; called by muse, mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as COSV55868319; called by pindel, varscan2
- KRT33B | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV52442646; called by muse, mutect2, varscan2
- KRT36 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100057595; called by muse, mutect2, varscan2
- KRT72 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as rs747007532, COSV99537344; called by muse, mutect2, varscan2
- KRT74 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs773585061, COSV99977563; called by muse, mutect2, varscan2
- KRT77 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs377759755; called by muse, mutect2, varscan2
- KRTAP2-4 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1205859112, COSV101224332; called by muse, mutect2, varscan2
- KSR1 | c.2042C>T p.T681M (on ENST00000644974 / NM_001367810.1; = p.T566M on NM_014238.2) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.633); catalogued as rs1363963229, COSV99258826; called by muse, mutect2, varscan2
- KSR2 | c.1751C>T p.T584M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs374020752; called by muse, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs770565486; called by mutect2, pindel, varscan2
- KTN1 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.971); catalogued as rs781690331, COSV101255261; called by muse, mutect2, varscan2
- KTN1 | c.3616C>T p.R1206* (on ENST00000395314 / NM_001271014.2; = p.R1177* on NM_004986.4) | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as rs138427703; called by muse, mutect2, varscan2
- LAMB2 | c.4876C>T p.R1626W | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs760301012, COSV100026128, COSV59730648, COSV59734923; called by muse, mutect2, varscan2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LAT2 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs202213143, COSV51921230; called by muse, mutect2, varscan2
- LCAT | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 126/289 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1417533036, CD044146, COSV50452949; called by muse, mutect2, varscan2
- LCE3A | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100175124; called by muse, mutect2, varscan2
- LGALS7B | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs762396841, COSV100153394; called by muse, mutect2, varscan2
- LGMN | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.226); catalogued as rs762575227, COSV58403864; called by muse, mutect2, varscan2
- LHX6 | c.793-1G>T p.X265_splice (on ENST00000373755 / NM_001242334.2; = p.X294_splice on NM_014368.5) | Splice Site (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100493479, COSV61344490, COSV61344774; called by muse, mutect2, varscan2
- LILRA4 | c.1229G>A p.S410N | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99393192; called by muse, varscan2
- LIMK2 | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749067206, COSV100058609; called by muse, varscan2
- LINS1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.075); catalogued as COSV100130298; called by muse, mutect2, varscan2
- LIPH | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs373209531; called by muse, mutect2, varscan2
- LMBRD1 | c.304T>G p.Y102D | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100992615; called by muse, mutect2, varscan2
- LONRF2 | c.2209A>G p.T737A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.514); catalogued as COSV101110973; called by muse, mutect2, varscan2
- LOXL3 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745944878, COSV99239745; called by muse, mutect2, varscan2
- LPCAT4 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100149049; called by muse, mutect2, varscan2
- LRP1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs914410104, COSV54528833; called by muse, mutect2, varscan2
- LRP1B | c.13351G>A p.V4451I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.146); catalogued as rs369522771, COSV67233837; called by muse, mutect2, varscan2
- LRP4 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.147); catalogued as rs752084061, COSV101066675; called by muse, mutect2, varscan2
- LRRC14 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs747101279, COSV99467726; called by muse, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC23 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.132); catalogued as rs537212288, COSV99145232; called by muse, mutect2, varscan2
- LRRC3 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs755355466, COSV52399666; called by muse, mutect2, varscan2
- LRRC4 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50814448; called by muse, mutect2, varscan2
- LRRC4B | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100975960; called by muse, mutect2, varscan2
- LRRC8C | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100968291; called by muse, mutect2, varscan2
- LTV1 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as rs201919461; called by muse, mutect2, varscan2
- LZTS1 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763490121, COSV99742601; called by muse, mutect2, varscan2
- LZTS2 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as rs949289879, COSV100932215; called by muse, mutect2, varscan2
- M1AP | c.601T>A p.S201T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.157); catalogued as COSV99304217; called by muse, mutect2, varscan2
- MACF1 | c.12954-1G>C p.X4318_splice (on ENST00000372915; = p.X2251_splice on NM_012090.5) | Splice Site (SNP) | VAF 20/36 reads (56%) | catalogued as COSV99245140; called by muse, mutect2, varscan2
- MAGEB10 | c.120del p.S41Lfs*6 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as COSV63310963, COSV63312330; called by mutect2, pindel, varscan2
- MAN2C1 | c.2666C>T p.A889V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs768526490, COSV99145475; called by muse, mutect2, varscan2
- MANBA | c.878A>G p.H293R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs1390934973, COSV99898837; called by muse, mutect2, varscan2
- MAP1A | c.3723G>A p.M1241I | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100288800; called by muse, mutect2, varscan2
- MAP2 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as COSV99560523; called by muse, mutect2, varscan2
- MAPK7 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100218967; called by muse, mutect2, varscan2
- MAPKAPK3 | c.800A>C p.N267T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV100781752; called by muse, mutect2, varscan2
- MAPRE3 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99251838; called by muse, mutect2, varscan2
- MARCHF9 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.54); catalogued as rs373196172; called by muse, mutect2, varscan2
- MARS1 | c.212del p.L71Cfs*33 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | catalogued as rs751080704; called by mutect2, varscan2
- MASP2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs370249422, COSV101280145; called by muse, mutect2, varscan2
- MAST2 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1291432726, COSV100788339; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MCF2L | c.2756G>A p.R919H (on ENST00000375608; = p.R887H on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56175387, COSV99996173; called by muse, mutect2, varscan2
- MCM3 | c.2211C>A p.D737E (on ENST00000229854 / NM_001366374.2; = p.D727E on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100008875; called by muse, mutect2, varscan2
- MDC1 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV64523865; called by muse, mutect2, varscan2
- MDFI | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as rs770572756, COSV100025688; called by muse, mutect2, varscan2
- MDN1 | c.8540G>A p.R2847H | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs150701881; called by muse, mutect2, varscan2
- MED12 | c.4385G>A p.R1462H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV61335886; called by muse, mutect2, varscan2
- MED12L | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.708); catalogued as COSV99853580; called by muse, mutect2, varscan2
- METTL3 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as rs750486834, COSV99398374; called by muse, mutect2, varscan2
- MFSD6 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as rs371311716; called by muse, mutect2, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | catalogued as rs769987847; called by mutect2, pindel, varscan2
- MICALL2 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as rs377174790; called by muse, mutect2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIER1 | c.452G>A p.R151H (on ENST00000355356 / NM_001077701.3; = p.R168H on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as rs762169502, COSV100591056; called by muse, mutect2, varscan2
- MINAR1 | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs779063853, COSV100548988, COSV59584250; called by muse, mutect2, varscan2
- MIS18BP1 | c.2596C>T p.H866Y | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100173057; called by muse, mutect2, varscan2
- MKI67 | c.8458A>G p.T2820A | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV100896673; called by muse, mutect2, varscan2
- MKI67 | c.3997C>G p.P1333A | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.145); catalogued as COSV100896674; called by muse, mutect2, varscan2
- MLN | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs746105078, COSV99803045; called by muse, mutect2
- MMADHC | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs1376956703, COSV57573293; called by muse, mutect2, varscan2
- MN1 | c.3862G>A p.D1288N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.206); catalogued as rs370142548; called by muse, mutect2, varscan2
- MOXD1 | c.1820C>T p.T607M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs142389314; called by muse, mutect2, varscan2
- MPP1 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.154); catalogued as rs1167015554, COSV65730294; called by muse, mutect2, varscan2
- MPST | c.409C>T p.R137C (on ENST00000341116 / NM_001369904.2; = p.R157C on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV100353381; called by muse, mutect2, varscan2
- MRPS14 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs139531485; called by muse, mutect2, varscan2
- MSANTD2 | c.1558G>A p.G520R (on ENST00000374979 / NM_001308027.2; = p.G468R on NM_024631.4) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.933); catalogued as rs758969628, COSV99515636; called by muse, mutect2, varscan2
- MST1 | c.1550G>A p.G517D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99610851; called by muse, mutect2, varscan2
- MTA2 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.062); catalogued as rs777136719, COSV99545387; called by muse, mutect2, varscan2
- MTA2 | c.1664del p.G555Afs*4 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as COSV53472599; called by mutect2, pindel, varscan2
- MTCL1 | c.1756G>A p.V586M (on ENST00000306329 / NM_001378206.1; = p.V226M on NM_015210.4) | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368971612; called by muse, mutect2, varscan2
- MTFMT | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99584392; called by muse, mutect2, varscan2
- MTNR1B | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0.014); catalogued as rs754089451, COSV57069050; called by muse, mutect2, varscan2
- MTTP | c.1843_1845del p.S615del | In Frame Del (DEL) | VAF 30/56 reads (54%) | catalogued as rs1185155591; called by pindel, varscan2
- MUC16 | c.28520C>T p.T9507M | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as rs370765065; called by muse, mutect2, varscan2
- MUC5B | c.8266G>A p.G2756R | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs779196227, COSV101500438; called by muse, mutect2, varscan2
- MVK | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as rs1055952433, CM114656, COSV99031333; called by muse, mutect2, varscan2
- MYBBP1A | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs758091815, COSV54606545; called by muse, mutect2, varscan2
- MYBPC3 | c.2179G>A p.V727M | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs564378953, COSV57029079; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MYH14 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as rs763292852, COSV99223108; called by muse, mutect2, varscan2
- MYH2 | c.5360G>A p.R1787Q | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs770182875, COSV55434133, COSV55439908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.484); catalogued as rs727503239, COSV100676711, COSV62454251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.3416G>A p.R1139H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV67963629, COSV67968113; called by muse, mutect2, varscan2
- MYH9 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1330043219, COSV99339124; called by muse, mutect2, varscan2
- MYLK2 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1249774186, COSV101044816; called by muse, mutect2, varscan2
- MYO15A | c.8731G>A p.V2911M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs747830108, COSV52760741; called by muse, mutect2, varscan2
- MYO1G | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs145057132; called by muse, mutect2, varscan2
- MYO7A | c.1623del p.K542Rfs*80 | Frame Shift Del (DEL) | VAF 17/36 reads (47%) | catalogued as COSV68685202; called by mutect2, pindel, varscan2
- MYO9A | c.7295C>T p.S2432L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs376627326; called by muse, mutect2, varscan2
- MYOF | c.4201C>T p.R1401C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs756925871, COSV100825842; called by muse, mutect2, varscan2
- MYOG | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.753); catalogued as COSV99613984; called by muse, mutect2, varscan2
- MYOM3 | c.40del p.R14Gfs*60 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as rs746493495; called by mutect2, pindel, varscan2
- NAALADL1 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs950333515, COSV60524823; called by muse, mutect2, varscan2
- NAP1L3 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100220425, COSV100220459; called by muse, mutect2, varscan2
- NARF | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.463); catalogued as rs752067226, COSV100559676; called by muse, mutect2, varscan2
- NBEAL1 | c.6176G>A p.R2059Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770739816, COSV101355542, COSV68915665; called by muse, mutect2, varscan2
- NBPF26 | c.2308G>A p.D770N (on ENST00000620612; = p.D508N on NM_001351372.1) | Missense Mutation (SNP) | VAF 84/100 reads (84%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as rs1553271805; called by muse, mutect2, varscan2
- NCKAP1L | c.2647T>G p.S883A | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV99515212; called by muse, mutect2, varscan2
- NCOR2 | c.6107G>A p.R2036H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as rs775458405, COSV62296573; called by muse, mutect2, varscan2
- NCOR2 | c.3646C>T p.R1216W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1408213259, COSV100657474; called by muse, mutect2
- NDRG3 | c.1009G>A p.G337S (on ENST00000349004 / NM_032013.4; = p.G325S on NM_022477.4) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs199920093, COSV100675398; called by muse, mutect2, varscan2
- NDST4 | c.1223A>G p.E408G | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as COSV99996821; called by muse, mutect2, varscan2
- NDUFA10 | c.604dup p.H202Pfs*25 | Frame Shift Ins (INS) | VAF 7/17 reads (41%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, varscan2
- NDUFB11 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.011); catalogued as rs782682185, COSV99333330; ClinVar: benign; called by muse, mutect2, varscan2
- NEDD4L | c.1676A>G p.H559R (on ENST00000400345 / NM_001144967.3; = p.H539R on NM_015277.6) | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs958611451, COSV99895267; called by muse, mutect2, varscan2
- NEFM | c.2716C>T p.H906Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs755073898, COSV99647382; called by muse, varscan2
- NEK2 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); catalogued as rs1411448957, COSV65355465; called by muse, mutect2, varscan2
- NFATC4 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs756434197, COSV51598468; called by muse, mutect2, varscan2
- NGFR | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV99412932; called by muse, mutect2, varscan2
- NLGN1 | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64335242; called by muse, mutect2, varscan2
- NLGN2 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs764447065, COSV57211225; called by muse, mutect2, varscan2
- NOL6 | c.1209G>A p.P403= | Splice Region (SNP) | VAF 10/27 reads (37%) | catalogued as rs552138670, COSV99954860; called by muse, mutect2, varscan2
- NOP2 | c.1733G>T p.G578V (on ENST00000322166 / NM_001258308.2; = p.G574V on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100351214; called by muse, mutect2, varscan2
- NOP53 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as rs1467314500, COSV55883015; called by muse, mutect2, varscan2
- NOTCH1 | c.583T>C p.C195R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53047355; called by muse, mutect2
- NOXA1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.127); catalogued as rs1196472760, COSV100395603; called by muse, mutect2, varscan2
- NPC1L1 | c.2675G>A p.R892H | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as rs773102499, COSV56928627; called by muse, mutect2, varscan2
- NPHP4 | c.4118G>A p.R1373Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768550124, COSV65397252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPR2 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs764163202, COSV100709510; called by muse, mutect2, varscan2
- NPR2 | c.2456G>A p.R819H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61042751; called by muse, mutect2, varscan2
- NPR3 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763038297, COSV54087281; called by muse, mutect2, varscan2
- NR0B1 | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as CM157273, COSV100973543; called by muse, mutect2, varscan2
- NR1H3 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0.182); catalogued as rs761873817, COSV101269779; called by muse, mutect2, varscan2
- NR2E1 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781361963, COSV64561688, COSV64562779; called by muse, mutect2, varscan2
- NRAP | c.4231C>T p.R1411C (on ENST00000359988 / NM_001322945.2; = p.R1376C on NM_006175.4) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs777292364, COSV100748476; called by muse, mutect2, varscan2
- NRK | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV54597186; called by muse, mutect2, varscan2
- NSD2 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56388725; called by muse, mutect2, varscan2
- NT5C1B | c.982G>A p.E328K (on ENST00000359846 / NM_001199086.2; = p.E268K on NM_033253.4) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1233128130, COSV58394486; called by muse, mutect2, varscan2
- NTN1 | c.1391G>A p.S464N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.159); catalogued as COSV99433223; called by muse, mutect2, varscan2
- NUFIP2 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs750934438, COSV99837517; called by muse, mutect2, varscan2
- NUGGC | c.2357C>A p.P786H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100429376; called by muse, mutect2
- NUGGC | c.1367G>T p.R456M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV100429382; called by muse, mutect2, varscan2
- NUP42 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV99331068; called by muse, mutect2, varscan2
- NXF1 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.242); catalogued as rs1432578586, COSV99586170; called by muse, mutect2, varscan2
- NXT1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV54782781; called by muse, mutect2, varscan2
- ODAPH | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs374774709; called by muse, mutect2, varscan2
- OGFOD2 | c.211C>T p.R71W (on ENST00000228922 / NM_001304833.1; = p.R11W on NM_024623.3) | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373563936; called by muse, mutect2, varscan2
- OR14I1 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.418); catalogued as rs772876095, COSV100700492, COSV61200709; called by muse, mutect2, varscan2
- OR1I1 | c.913A>G p.I305V | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99264809; called by muse, mutect2, varscan2
- OR1K1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs867239913, COSV99474304; called by muse, mutect2, varscan2
- OR2W1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as COSV101013921; called by muse, mutect2, varscan2
- OR4C3 | c.89del p.L30Cfs*2 | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | catalogued as COSV99082006; called by mutect2, pindel, varscan2
- OR6T1 | c.50T>G p.F17C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100190027; called by muse, mutect2, varscan2
- OR7A10 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 25/50 reads (50%) | catalogued as COSV99932483; called by muse, mutect2, varscan2
- OSBPL2 | c.1411C>T p.R471W (on ENST00000313733 / NM_144498.4; = p.R459W on NM_014835.4) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374024313; called by muse, mutect2, varscan2
- OSBPL6 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.83); catalogued as rs199651479, COSV99507704; called by muse, mutect2, varscan2
- OSGIN2 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs201554027, COSV52412274; called by muse, mutect2, varscan2
- OTUD6B | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs377632239; called by muse, mutect2, varscan2
- P2RX1 | c.135C>T p.I45= | Splice Region (SNP) | VAF 33/74 reads (45%) | catalogued as rs778913132, COSV99844793; called by muse, mutect2, varscan2
- PABPC1L | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as rs775637956, COSV53841232; called by muse, mutect2, varscan2
- PABPC1L | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs575662446, COSV53839412; called by muse, mutect2, varscan2
- PABPC5 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV100442462, COSV100442605; called by muse, mutect2, varscan2
- PAGE3 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV100891993, COSV100891999; called by muse, mutect2, varscan2
- PALM | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99214574; called by muse, mutect2, varscan2
- PAMR1 | c.1819G>A p.V607M (on ENST00000619888 / NM_001001991.3; = p.V624M on NM_015430.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs148541461, COSV53517310; called by muse, mutect2, varscan2
- PANX2 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs755473922, COSV99348397; called by muse, mutect2, varscan2
- PAOX | c.1160A>C p.E387A | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV99529906; called by muse, mutect2
- PARP10 | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs782088818, COSV100478095; called by muse, mutect2, varscan2
- PARP8 | c.2474G>A p.G825D | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55859096; called by muse, mutect2, varscan2
- PAX4 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as rs748573868, COSV100489975, COSV100490067; called by muse, mutect2, varscan2
- PCDH12 | c.2052dup p.Q686Tfs*102 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | catalogued as rs748127746; called by mutect2, varscan2
- PCDHA11 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.104); catalogued as rs376620715, COSV56521586; called by muse, mutect2, varscan2
- PCDHA3 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65366607; called by muse, mutect2, varscan2
- PCDHB1 | c.2336C>A p.P779H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100128233, COSV60629517; called by muse, mutect2, varscan2
- PCDHB10 | c.726T>G p.F242L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV99504503; called by muse, mutect2, varscan2
- PCDHB11 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.532); catalogued as rs781977311, COSV100697042; called by muse, mutect2, varscan2
- PCDHB12 | c.1287del p.R430Gfs*2 | Frame Shift Del (DEL) | VAF 31/83 reads (37%) | catalogued as COSV53398711; called by mutect2, pindel, varscan2
- PCDHB13 | c.1715G>A p.C572Y | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV99507402; called by muse, mutect2, varscan2
- PCDHB4 | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV52022492; called by muse, mutect2, varscan2
- PCDHB6 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV50692259; called by muse, mutect2, varscan2
- PCDHGB3 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54019967; called by muse, mutect2, varscan2
- PCDHGC4 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.041); catalogued as rs771744120, COSV99340633; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 12/25 reads (48%) | catalogued as COSV61618667; called by mutect2, varscan2
- PDE2A | c.1910C>A p.P637Q | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV100558096; called by muse, mutect2, varscan2
- PDE4D | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.984); catalogued as rs774486077, COSV72353481, COSV72355966; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE6C | c.1578A>G p.I526M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV101008781; called by muse, mutect2, varscan2
- PDP2 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs756089009, COSV61241503; called by muse, mutect2, varscan2
- PEAR1 | c.2498del p.P833Hfs*87 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs760058297; called by mutect2, pindel, varscan2
- PER1 | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs763476231, COSV100424622; called by muse, mutect2, varscan2
- PEX12 | c.771_773del p.F257del | In Frame Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs1567729860; called by pindel, varscan2
- PFKFB1 | c.226T>C p.F76L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | PolyPhen probably damaging (0.996); catalogued as COSV100895747; called by muse, mutect2, varscan2
- PFKFB2 | c.560T>C p.M187T | Missense Mutation (SNP) | VAF 20/37 reads (54%) | PolyPhen benign (0.019); catalogued as COSV100892007; called by muse, mutect2, varscan2
- PGM2L1 | c.1038-1G>A p.X346_splice | Splice Site (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99994987; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 16/20 reads (80%) | catalogued as rs769717544; called by mutect2, varscan2
- PHKA2 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1555988071, CM991039, COSV101177176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHYHD1 | c.517G>A p.V173M (on ENST00000372592 / NM_001100876.2; = p.A165= on NM_174933.4) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs371562024; called by muse, mutect2, varscan2
- PIGO | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as rs759288021, COSV99956757; called by muse, mutect2, varscan2
- PIGR | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100732535; called by muse, mutect2, varscan2
- PITPNM1 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs938439836, COSV62709740; called by muse, mutect2, varscan2
- PITRM1 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs546803161, COSV56539588; called by muse, mutect2, varscan2
- PKD1 | c.12767C>T p.A4256V (on ENST00000262304 / NM_001009944.3; = p.A4255V on NM_000296.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV99238338; called by muse, mutect2
- PKD1L1 | c.4738C>T p.R1580W | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs762682035, COSV56977414; called by muse, mutect2, varscan2
- PLA2G4A | c.1670C>A p.P557Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100820583; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs745860467; called by mutect2, varscan2
- PLCD1 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99378961; called by muse, mutect2, varscan2
- PLCD3 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755179990, COSV59561976; called by muse, mutect2, varscan2
- PLCG2 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.998); catalogued as rs761094228, COSV63867788; called by muse, mutect2, varscan2
- PLCH1 | c.2342T>C p.V781A (on ENST00000340059 / NM_001130960.2; = p.V793A on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100397238; called by muse, mutect2, varscan2
- PLD2 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs761911354, COSV99562444; called by muse, varscan2
- PLEKHG7 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as rs370641297, COSV60821279; called by muse, mutect2, varscan2
- PLEKHH3 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as COSV52219879; called by muse, mutect2, varscan2
- PLK1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100267292; called by muse, mutect2, varscan2
- PLOD1 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755346019, COSV52143608; called by muse, mutect2, varscan2
- PLXNA1 | c.2468A>T p.D823V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV99303349; called by muse, mutect2, varscan2
- PLXNA3 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs782122729, COSV100860035; called by muse, mutect2, varscan2
- PLXNA3 | c.5443C>T p.R1815C | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100860036; called by muse, mutect2, varscan2
- PLXNA4 | c.3784C>T p.R1262C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339626384, COSV100324940; called by muse, mutect2, varscan2
- PLXNA4 | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs756544431, COSV100322604; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as rs782076287; called by mutect2, varscan2
- PLXND1 | c.3967C>T p.R1323C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60711669; called by muse, mutect2
- PLXND1 | c.2705C>A p.P902Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs775659642, COSV100139940; called by muse, mutect2, varscan2
- PMPCA | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.698); catalogued as rs1472486098, COSV65510354; called by muse, mutect2, varscan2
- PNMT | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs5642; called by muse, mutect2, varscan2
- POLR1E | c.1046G>A p.R349Q (on ENST00000377792 / NM_001282766.1; = p.R287Q on NM_022490.4) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.748); catalogued as rs745330508, COSV66773064; called by muse, mutect2, varscan2
- POTEE | c.2057del p.K686Rfs*6 | Frame Shift Del (DEL) | VAF 74/96 reads (77%) | catalogued as rs772047281; called by mutect2, varscan2
- PPFIA1 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | catalogued as COSV99557600; called by muse, mutect2, varscan2
- PPFIA1 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs778116748, COSV99557601; called by muse, mutect2, varscan2
- PPID | c.600C>A p.D200E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV100306870; called by muse, mutect2
- PPM1G | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1239643465, COSV59768338; called by muse, mutect2
- PPM1J | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs536445102, COSV53519027; called by muse, mutect2, varscan2
- PPP1R10 | c.930del p.V311Yfs*79 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs746108087; called by mutect2, varscan2
- PPP1R12C | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99670257; called by muse, mutect2, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs758484975; called by mutect2, varscan2
- PPWD1 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs143955881; called by muse, mutect2, varscan2
- PRDM4 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as rs142942388; called by muse, mutect2, varscan2
- PRICKLE3 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113244888, COSV66234488; called by muse, mutect2, varscan2
- PRKAG2 | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.096); catalogued as rs540525001, COSV55237918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCSH | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99371689; called by muse, mutect2, varscan2
- PRORP | c.1675C>G p.P559A | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99155775; called by muse, mutect2, varscan2
- PROSER3 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748701598, COSV99994589; called by muse, mutect2, varscan2
- PRSS57 | c.311G>C p.G104A | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as COSV100249589; called by muse, mutect2
- PRUNE2 | c.6307G>A p.D2103N | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1423147914, COSV65038064; called by muse, mutect2, varscan2
- PSG5 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs775366471, COSV61654043; called by muse, mutect2
- PSMD12 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1422276648, COSV100635365; called by muse, mutect2, varscan2
- PSME4 | c.5224C>T p.R1742* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | catalogued as rs775389448, COSV101122542; called by muse, mutect2, varscan2
- PSMG3 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV99365871; called by muse, mutect2, varscan2
- PTEN | c.800dup p.D268Gfs*30 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | catalogued as COSV64302388; called by mutect2, pindel, varscan2
- PTGFR | c.1052C>G p.P351R | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100882318, COSV66115916; called by muse, mutect2, varscan2
- PTPRB | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99717824; called by muse, mutect2, varscan2
- PUM1 | c.3197G>A p.R1066Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1381197998, COSV99928307; called by muse, mutect2, varscan2
- PVRIG | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); catalogued as rs538515532, COSV99443915; called by muse, mutect2, varscan2
- PWWP3A | c.206C>T p.A69V (on ENST00000627377; = p.A68V on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.55); catalogued as COSV100262074; called by muse, mutect2, varscan2
- PYCR2 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100661528; called by muse, mutect2, varscan2
- PYGB | c.1753G>A p.V585I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763681247, COSV99405194; called by muse, mutect2, varscan2
- QRICH1 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.586); catalogued as rs1206930424, COSV100676747; called by muse, mutect2, varscan2
- RAB40AL | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV99505138; called by muse, mutect2, varscan2
- RAB4A | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs779345299, COSV64207144; called by muse, mutect2, varscan2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 29/60 reads (48%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RAD54L | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1363172157, COSV100914797, COSV64335565; called by muse, mutect2, varscan2
- RAD9A | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as rs569583450, COSV57236269; called by muse, mutect2, varscan2
- RALGAPA2 | c.1519G>A p.G507S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1366495521, COSV99173849; called by muse, mutect2, varscan2
- RANBP2 | c.1642G>A p.V548I | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1057954, COSV99312429; called by muse, mutect2, varscan2
- RAPGEF1 | c.2917G>A p.A973T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs553644640, COSV100940636; called by muse, mutect2, varscan2
- RAPSN | c.854A>G p.Q285R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1216195553, COSV100100262; called by muse, mutect2, varscan2
- RASSF7 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV100272654; called by muse, mutect2, varscan2
- RBCK1 | c.253A>G p.K85E (on ENST00000356286 / NM_031229.4; = p.K43E on NM_006462.6) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100675858; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM33 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1455453530, COSV56638823; called by muse, mutect2, varscan2
- RDH8 | c.857C>T p.T286M (on ENST00000651512; = p.T266M on NM_015725.4) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs745469395, COSV50674145; called by muse, mutect2, varscan2
- RELCH | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.381); catalogued as COSV56882513; called by muse, mutect2, varscan2
- REM2 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs143212029; called by muse, mutect2, varscan2
- RET | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100393850; called by muse, mutect2, varscan2
- RFPL2 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768072734; called by muse, mutect2, varscan2
- RGL2 | c.608del p.G203Afs*49 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs762949421; called by mutect2, varscan2
- RGS12 | c.3004G>A p.A1002T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as rs780994392, COSV100122992; called by muse, mutect2, varscan2
- RGS5 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.12); catalogued as rs764215537, COSV100009154; called by muse, mutect2, varscan2
- RHBDF1 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs140406683; called by muse, varscan2
- RHOXF2 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.142); catalogued as rs782304633, COSV65047947; called by muse, mutect2, varscan2
- RIMS2 | c.4027C>T p.R1343W | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs754798117, COSV51650723; called by muse, mutect2, varscan2
- RIOK3 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs199977739, COSV100259283, COSV100259362; called by muse, mutect2, varscan2
- RITA1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs367637594; called by muse, mutect2, varscan2
- RNASE9 | c.572A>G p.H191R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.651); catalogued as COSV100141267; called by muse, mutect2
- RNF215 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs767239636, COSV53176309; called by muse, mutect2, varscan2
- RNF40 | c.2832G>A p.A944= | Splice Region (SNP) | VAF 10/17 reads (59%) | catalogued as COSV99354865; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF43 | c.1322del p.P441Lfs*61 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs755967475, COSV68457961; called by mutect2, pindel, varscan2
- ROPN1 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99481452; called by mutect2, varscan2
- ROR2 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs146127454, COSV100995883; called by muse, mutect2, varscan2
- RORB | c.949A>G p.R317G (on ENST00000396204 / NM_001365023.1; = p.R306G on NM_006914.4) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100974371; called by muse, mutect2, varscan2
- RPAP1 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100427181, COSV58543019; called by muse, mutect2, varscan2
- RPF1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.072); catalogued as rs150125636; called by muse, mutect2, varscan2
- RPL10 | c.524A>G p.K175R | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.238); catalogued as COSV99186017; called by muse, mutect2
- RPL13 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs772105032, COSV100276301, COSV100276355; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 18/33 reads (55%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
827 further variants in this file (428 protein-altering or splice-affecting, 361 silent, 38 other) are not listed here.
